Somatic mutation profile of tumor specimen TCGA-P5-A5F1-01A (aliquot TCGA-P5-A5F1-01A-11D-A289-08) from TCGA case TCGA-P5-A5F1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.3 years (11,070 days).
Specimen TCGA-P5-A5F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 056ae545-8eaf-4085-8860-4762a5ff0b02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5F1-10A (Blood Derived Normal), aliquot TCGA-P5-A5F1-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3648f974-971c-4b9b-a705-92e879928c89

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.4633G>A p.V1545I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as rs1161854773; called by muse, mutect2, varscan2
- ATRX | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 91/131 reads (69%) | catalogued as COSV64870592, COSV64871923; called by muse, mutect2, varscan2
- C1QTNF1 | c.527A>C p.D176A | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59260692; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs200974337, COSV55828427; called by muse, mutect2, varscan2
- CR1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756455451, COSV65455950; called by muse, mutect2
- MKI67 | c.4538G>A p.R1513K | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV64072694; called by muse, mutect2
- MMRN2 | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100922686; called by mutect2, varscan2
- NYNRIN | c.3617G>A p.G1206D | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV66841244, COSV66842096, COSV66845720; called by muse, mutect2, varscan2
- PEG3 | c.4642C>T p.R1548C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs576263292, COSV55625716; called by muse, mutect2, varscan2
- TFAP4 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV99200108; called by muse, mutect2
- TNRC6A | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100170614; called by muse, mutect2
- TTN | c.89227A>C p.S29743R (on ENST00000591111; = p.S22319R on NM_003319.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | PolyPhen possibly damaging (0.447); catalogued as COSV59901793; called by muse, mutect2, varscan2
- PPP4R1 | c.615G>T p.G205= (on ENST00000400556 / NM_001042388.3; = p.G188= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- ZNF260 | c.732A>G p.G244= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV72951158; called by muse, mutect2, varscan2
- SNORD115-29 | n.46C>T | RNA (SNP) | VAF 18/602 reads (3%) | called by muse, mutect2
- TRIM6 | c.-11G>A | 5'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53474708; called by muse, mutect2, varscan2
